Somatic mutation profile of tumor specimen TCGA-PG-A914-01A (aliquot TCGA-PG-A914-01A-11D-A37N-09) from TCGA case TCGA-PG-A914, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 73.9 years (26,992 days).
Specimen TCGA-PG-A914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88a83f6f-615e-4523-b339-7b481ff89066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PG-A914-10A (Blood Derived Normal), aliquot TCGA-PG-A914-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d20d6c8-6851-48fd-8482-89e9c3cdf5fb

The open-access MAF lists 138 somatic variants for this specimen: 107 protein-altering or splice-affecting, 26 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 26, Nonsense Mutation 12, Splice Site 3, 5'Flank 2, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- AKR7L | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101334218, COSV70168098; called by muse, mutect2, varscan2
- ANP32E | c.705T>G p.Y235* | Nonsense Mutation (SNP) | VAF 163/237 reads (69%) | catalogued as COSV100029583; called by muse, mutect2, varscan2
- ARID1A | c.6670G>C p.E2224Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100250527; called by muse, mutect2, varscan2
- ATP7A | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100430328; called by muse, mutect2, varscan2
- BAIAP2L2 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100207067; called by muse, mutect2, varscan2
- BMP5 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63706639; called by muse, mutect2, varscan2
- BMS1 | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 94/267 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs370660287; called by muse, mutect2, varscan2
- BNIPL | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs749200773, COSV99764537; called by muse, mutect2, varscan2
- BTBD7 | c.2143G>C p.D715H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV58287621; called by muse, mutect2, varscan2
- CAPN1 | c.443T>C p.I148T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99658410; called by muse, mutect2, varscan2
- CASTOR1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV99304497; called by muse, mutect2
- CCDC126 | c.125G>A p.S42N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100277845; called by muse, mutect2, varscan2
- CD109 | c.2387C>G p.S796* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99752765; called by muse, mutect2
- CDC27 | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.444); catalogued as COSV99294058; called by mutect2, varscan2
- CDON | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99700747; called by muse, mutect2
- CEP126 | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV99680682; called by muse, mutect2, varscan2
- CFAP54 | c.5200G>A p.D1734N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.31); catalogued as rs760850219, COSV100732991; called by muse, mutect2, varscan2
- CHRNB4 | c.478T>G p.F160V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929209; called by muse, mutect2, varscan2
- CIBAR2 | c.217G>C p.E73Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV101608262; called by muse, mutect2, varscan2
- CNGA1 | c.1324A>T p.K442* | Nonsense Mutation (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100652145; called by muse, mutect2
- CNNM4 | c.2213C>G p.T738S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV100998608, COSV65662287; called by muse, mutect2, varscan2
- CPSF1 | c.2842C>A p.P948T | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV100450240; called by muse, mutect2, varscan2
- CSMD1 | c.5405C>T p.P1802L (on ENST00000520002; = p.P1801L on NM_033225.6) | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100144602; called by muse, mutect2, varscan2
- CSMD1 | c.1717C>T p.Q573* (on ENST00000520002; = p.Q572* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV100144606; called by muse, mutect2, varscan2
- CSMD2 | c.4199G>A p.S1400N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs936003314, COSV99586797; called by muse, mutect2, varscan2
- CSMD3 | c.9964A>T p.I3322L (on ENST00000297405 / NM_001363185.1; = p.I3153L on NM_052900.3) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1347376797, COSV99826549, COSV99835214; called by muse, mutect2, varscan2
- DTNA | c.1611G>C p.E537D | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.989); catalogued as rs1477078144, COSV99311191; called by muse, mutect2, varscan2
- DYNC2I1 | c.3020C>T p.A1007V | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377528954; called by muse, mutect2, varscan2
- EMC1 | c.1928T>C p.I643T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1307511146, COSV100916423; called by muse, mutect2, varscan2
- ENTPD5 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (0.977); catalogued as COSV100592150; called by muse, mutect2, varscan2
- FAM83B | c.1532C>G p.S511* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV100174111; called by muse, mutect2, varscan2
- FCHO1 | c.2005G>A p.G669R | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs750801082, COSV53181635, COSV99406256; called by muse, mutect2, varscan2
- FKBP4 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV99133582; called by muse, mutect2
- FRMD7 | c.1977A>T p.K659N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100048718; called by muse, mutect2, varscan2
- GBGT1 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100923756, COSV100923769; called by muse, mutect2, varscan2
- GIPC1 | c.239A>C p.K80T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV100600015; called by muse, mutect2, varscan2
- GLI3 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1346124250, COSV67887149; called by muse, mutect2
- GRID1 | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100022236; called by muse, mutect2, varscan2
- GSN | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs755696871, COSV100375856; called by muse, mutect2, varscan2
- GYG2 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs192438244, COSV58549130; called by muse, mutect2, varscan2
- HAPLN1 | c.101-2A>G p.X34_splice | Splice Site (SNP) | VAF 6/8 reads (75%) | catalogued as COSV99164609; called by muse, mutect2, varscan2
- HFE | c.684G>C p.L228F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100352509, COSV58513966; called by muse, mutect2, varscan2
- HMCES | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as rs769685234, COSV100135403; called by muse, mutect2, varscan2
- HOOK1 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100968990; called by muse, mutect2, varscan2
- HSD17B7 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs756796880, COSV99597599; called by muse, mutect2, varscan2
- ITGAX | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs777199815, COSV51645222; called by muse, mutect2, varscan2
- KIAA2026 | c.4199C>G p.S1400C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV101198878; called by muse, mutect2
- LAMC3 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs369660174; called by muse, varscan2
- LZTS3 | c.159G>C p.K53N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV100232163; called by muse, mutect2
- MBNL1 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361852660, COSV99219683; called by mutect2, varscan2
- MED12 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs875989806, COSV61337658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFHAS1 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs144338243, COSV99359248; called by muse, mutect2, varscan2
- MGA | c.4861G>A p.V1621M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs780419344, COSV99578661; called by muse, mutect2, varscan2
- MNT | c.1342C>T p.H448Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99437955; called by muse, mutect2
- MPHOSPH10 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99731016; called by muse, mutect2, varscan2
- MRFAP1 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV100307554, COSV57994740; called by muse, mutect2, varscan2
- MYNN | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV100581810, COSV62990922; called by muse, mutect2, varscan2
- MYO16 | c.3903G>C p.K1301N | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100696009; called by muse, mutect2, varscan2
- NDUFB8 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100144035, COSV54511788; called by muse, mutect2
- NOX5 | c.1629G>C p.K543N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.131); catalogued as COSV99533380; called by muse, mutect2, varscan2
- OR6Q1 | c.936C>A p.N312K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100109456, COSV56933747; called by muse, mutect2, varscan2
- PAH | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100187701; called by muse, mutect2
- PBRM1 | c.2524G>C p.E842Q | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV56271770, COSV99967618; called by muse, mutect2, varscan2
- PCDH15 | c.4108C>G p.L1370V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100216282; called by muse, mutect2, varscan2
- PCLO | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV100428074; called by muse, mutect2, varscan2
- PDE12 | c.326C>A p.S109* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | catalogued as COSV100239721, COSV60818144; called by muse, mutect2
- PDE7A | c.622C>G p.Q208E (on ENST00000401827 / NM_001242318.3; = p.Q182E on NM_002603.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.095); catalogued as rs756238378, COSV101052612; called by muse, mutect2, varscan2
- PFKFB2 | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | PolyPhen benign (0.228); catalogued as COSV100891888; called by muse, mutect2, varscan2
- PKD1 | c.10395C>G p.F3465L (on ENST00000262304 / NM_001009944.3; = p.F3464L on NM_000296.4) | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1363762131, COSV51914205, COSV51915051; called by muse, mutect2, varscan2
- PKDREJ | c.5100G>T p.K1700N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV53552982, COSV99478485; called by mutect2, varscan2
- PLEKHH2 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425684686, COSV99174378; called by muse, mutect2, varscan2
- PNN | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs866120482, COSV53767204; called by muse, mutect2, varscan2
- PRICKLE2 | c.1576G>A p.E526K (on ENST00000295902; = p.E470K on NM_198859.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.46); catalogued as COSV99896711; called by muse, mutect2, varscan2
- PTPRB | c.3631C>A p.P1211T | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV99716134; called by muse, mutect2, varscan2
- PTPRD | c.1604C>G p.S535C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771630160, COSV100643656, COSV100647918; called by muse, mutect2, varscan2
- RABGGTB | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99590821; called by muse, mutect2, varscan2
- RHAG | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100006392; called by muse, mutect2, varscan2
- RPL3 | c.689-1G>C p.X230_splice | Splice Site (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99335086; called by muse, mutect2
- SAMM50 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as COSV100601259; called by muse, mutect2, varscan2
- SATB2 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99610683; called by muse, varscan2
- SCCPDH | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV100829711; called by muse, mutect2, varscan2
- SCNN1A | c.1226C>G p.S409* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV99964545; called by muse, mutect2
- SFMBT2 | c.655C>G p.R219G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100738497, COSV62817263; called by muse, mutect2, varscan2
- SGSM1 | c.3218T>C p.V1073A (on ENST00000400359 / NM_001039948.4; = p.V1012A on NM_133454.3) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV101240470; called by muse, mutect2, varscan2
- SI | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100014303; called by muse, mutect2, varscan2
- SKIL | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99378096; called by muse, mutect2, varscan2
- SLC25A45 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748470616, COSV99587247; called by muse, mutect2, varscan2
- SLC9A2 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 26/33 reads (79%) | catalogued as COSV52131432, COSV99295912; called by muse, mutect2, varscan2
- SPAG9 | c.3871G>C p.E1291Q (on ENST00000262013 / NM_001130528.3; = p.E1277Q on NM_003971.6) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV100004608; called by muse, mutect2
- SPAG9 | c.3314C>A p.S1105Y (on ENST00000262013 / NM_001130528.3; = p.S1091Y on NM_003971.6) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100004618; called by muse, mutect2, varscan2
- SRCAP | c.5617C>T p.R1873* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs766102471, COSV52682566, COSV99349456; called by muse, mutect2, varscan2
- TLR7 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101027749; called by muse, mutect2, varscan2
- TRIM51 | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 43/290 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99792211, COSV99793004; called by muse, mutect2, varscan2
- TRIOBP | c.6670G>A p.E2224K (on ENST00000644935 / NM_001039141.3; = p.E511K on NM_007032.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100730653; called by muse, mutect2, varscan2
- UROC1 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99330943; called by muse, mutect2, varscan2
- VPS41 | c.247-1G>C p.X83_splice | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV99730620; called by muse, mutect2, varscan2
- WAS | c.926G>C p.R309P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100939440, COSV64996604; called by muse, mutect2, varscan2
- WDFY3 | c.6904C>G p.L2302V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV99882321; called by muse, mutect2, varscan2
- XKR3 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100509144; called by muse, mutect2, varscan2
- ZC4H2 | c.242A>T p.K81I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100564787; called by muse, mutect2, varscan2
- DOCK1 | c.3448del p.D1150Ifs*22 | Frame Shift Del (DEL) | VAF 19/29 reads (66%) | called by mutect2, pindel, varscan2
- EHD4 | c.1186dup p.L396Pfs*105 | Frame Shift Ins (INS) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- NLRX1 | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2
- PREPL | c.1205_1221del p.K402Tfs*22 | Frame Shift Del (DEL) | VAF 25/60 reads (42%) | called by mutect2, pindel, varscan2
- SPATA16 | c.1198dup p.I400Nfs*13 | Frame Shift Ins (INS) | VAF 29/80 reads (36%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.3351G>A p.V1117= (on ENST00000370717 / NM_001366005.1; = p.V1104= on NM_012302.4) | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99587367; called by muse, mutect2, varscan2
- CDC42EP2 | c.165C>T p.I55= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV99659094; called by muse, mutect2, varscan2
- CFAP206 | c.969C>T p.F323= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99739195; called by muse, mutect2, varscan2
- CHCHD2 | c.423G>A p.L141= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs377573135, COSV101271034; called by muse, mutect2, varscan2
- CLK3 | c.1254C>T p.A418= (on ENST00000395066 / NM_001130028.1; = p.A270= on NM_003992.4) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100165804; called by muse, mutect2, varscan2
- ENTPD4 | c.1782G>A p.R594= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1281274169, COSV62268473; called by muse, mutect2, varscan2
- GFI1B | c.987C>G p.L329= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- IMPG2 | c.435C>T p.V145= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV51986431; called by muse, mutect2
- KCNB2 | c.1347C>T p.I449= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs781521472, COSV101578684, COSV101579115; called by muse, mutect2, varscan2
- LRRC7 | c.795G>A p.G265= (on ENST00000651989 / NM_001370785.2; = p.G232= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV50597844; called by muse, mutect2, varscan2
- MYO18B | c.6891C>T p.D2297= | Silent (SNP) | VAF 39/44 reads (89%) | catalogued as rs374327917; called by muse, mutect2, varscan2
- MYT1 | c.411C>G p.V137= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV60512217; called by muse, mutect2
- NKX6-1 | c.817T>C p.L273= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV99879948; called by muse, mutect2, varscan2
- NPAP1 | c.399G>A p.P133= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs750902724, COSV61504850; called by muse, mutect2, varscan2
- NRXN3 | c.1323G>A p.E441= (on ENST00000335750 / NM_001330195.2; = p.E68= on NM_004796.6) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100201247, COSV59743907; called by muse, mutect2, varscan2
- OR5A1 | c.753G>T p.V251= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100118278; called by muse, mutect2, varscan2
- OR5H14 | c.765C>T p.L255= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs140385435; called by muse, mutect2, varscan2
- OXTR | c.822C>T p.V274= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100373060; called by muse, mutect2, varscan2
- PCDHB14 | c.162G>A p.L54= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs143061094; called by muse, mutect2, varscan2
- PHKA2 | c.1464G>A p.R488= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV101176742; called by muse, mutect2, varscan2
- PLAA | c.42C>G p.L14= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV101263492; called by muse, mutect2
- RBMXL2 | c.696C>T p.A232= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs749129303, COSV100182090; called by muse, mutect2, varscan2
- RPAP3 | c.942T>A p.A314= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as COSV99139281; called by muse, mutect2, varscan2
- RYR2 | c.3075G>A p.K1025= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100768389; called by muse, mutect2, varscan2
- TRIM15 | c.858G>T p.A286= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100938785, COSV64988997; called by muse, varscan2
- ZNF721 | c.1764G>A p.L588= (on ENST00000338977; = p.L600= on NM_133474.4) | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV100167092; called by muse, mutect2, varscan2
- ATP6V0E2 | c.*114C>T | 3'UTR (SNP) | VAF 6/50 reads (12%) | catalogued as rs974179353, COSV101374573; called by muse, mutect2, varscan2
- GORAB | chr1:170532164 G>C | 5'Flank (SNP) | VAF 66/123 reads (54%) | catalogued as COSV100883757; called by muse, mutect2, varscan2
- RNU7-174P | chr8:80558993 A>C | 5'Flank (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- STK3 | c.352-15539C>G | Intron (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- SWI5 | c.-108G>A | 5'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100199571; called by muse, mutect2
